Somatic mutation profile of tumor specimen TCGA-XF-A9T8-01A (aliquot TCGA-XF-A9T8-01A-11D-A391-08) from TCGA case TCGA-XF-A9T8, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 64.1 years (23,403 days).
Specimen TCGA-XF-A9T8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db9cc2b3-a1ac-47cd-8fd4-a8339ff0e3b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9T8-10A (Blood Derived Normal), aliquot TCGA-XF-A9T8-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab54d615-5341-41b2-ad6d-682ba0fa51dc

The open-access MAF lists 792 somatic variants for this specimen: 570 protein-altering or splice-affecting, 205 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 499, Silent 205, Nonsense Mutation 62, Intron 9, RNA 4, Frame Shift Del 3, 3'Flank 2, Splice Site 2, Splice Region 2, 5'UTR 1, In Frame Del 1, Translation Start Site 1.

Variants (750 of 792; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRA1 | c.973T>C p.F325L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1064794681, COSV50104392; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.14659G>T p.E4887* | Nonsense Mutation (SNP) | VAF 22/116 reads (19%) | catalogued as rs793888513, CM156943, COSV56439572, COSV99976438; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RUNX1 | c.249G>C p.K83N (on ENST00000344691 / NM_001001890.3; = p.K110N on NM_001754.5) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1569084082, COSV55868575, COSV55875639; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASS | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62790026; called by muse, mutect2, varscan2
- ABCC5 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs368494058; called by muse, mutect2, varscan2
- AC131160.1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV57700692; called by muse, mutect2, varscan2
- ACACB | c.4696G>A p.E1566K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58134703; called by muse, mutect2, varscan2
- ACBD6 | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.784); catalogued as COSV62573634; called by muse, mutect2, varscan2
- ACOT12 | c.131A>T p.E44V | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100296596; called by muse, mutect2
- ACOT12 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100296598, COSV56897382; called by muse, mutect2
- ACTN4 | c.2013G>T p.E671D | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV99399658; called by muse, mutect2
- ADAMTS15 | c.791T>C p.I264T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV54505481; called by muse, mutect2
- ADAMTS18 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs773401732, COSV51410220, COSV51421023; called by muse, mutect2, varscan2
- ADAMTS20 | c.4502G>A p.R1501K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.476); catalogued as COSV67131531; called by muse, mutect2, varscan2
- ADNP2 | c.3146G>A p.R1049H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.933); catalogued as rs145603867; called by muse, mutect2
- AFAP1 | c.1331C>G p.T444R | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV61795646; called by muse, mutect2, varscan2
- AGA | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV52806292; called by muse, mutect2, varscan2
- AGBL2 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV54092035; called by muse, mutect2, varscan2
- AGT | c.1051T>C p.S351P | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV64184579; called by muse, mutect2, varscan2
- AHNAK | c.17410G>T p.G5804W | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57213377; called by muse, mutect2, varscan2
- AHNAK | c.15004G>A p.E5002K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.969); catalogued as rs893194788, COSV57211366, COSV57213384; called by muse, mutect2, varscan2
- AJAP1 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65450828; called by muse, mutect2, varscan2
- AKAP9 | c.1708G>C p.D570H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs778811102, COSV62346336, COSV62360634; called by muse, mutect2, varscan2
- AKAP9 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62346354; called by muse, mutect2, varscan2
- AKAP9 | c.5842G>C p.E1948Q (on ENST00000359028; = p.E1916Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100661756; called by muse, mutect2
- ANAPC4 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.852); catalogued as COSV59544135, COSV59546528; called by muse, mutect2, varscan2
- ANK3 | c.1783G>C p.G595R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55057955; called by muse, mutect2, varscan2
- ANKIB1 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.656); catalogued as COSV56061499; called by muse, mutect2
- AP1G1 | c.1825C>G p.P609A | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV55489327; called by muse, mutect2, varscan2
- APOB | c.3346G>T p.E1116* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as rs1324395284, COSV99262801; called by muse, mutect2, varscan2
- APOL5 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV50766337, COSV50766937; called by muse, mutect2
- ARHGAP20 | c.3086C>G p.S1029C | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV52811354, COSV52819056; called by muse, mutect2, varscan2
- ARHGAP30 | c.2212G>A p.G738R | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV63516563; called by muse, mutect2, varscan2
- ARHGAP9 | c.245A>T p.Y82F | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62722504; called by muse, mutect2, varscan2
- ARHGEF11 | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV63812509; called by muse, mutect2, varscan2
- ARID1A | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61377685; called by muse, mutect2, varscan2
- ARID4A | c.2701G>C p.E901Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.419); catalogued as COSV62163733, COSV62165735; called by muse, mutect2, varscan2
- ARRB1 | c.951C>G p.I317M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV63575535; called by muse, mutect2, varscan2
- ASL | c.1129C>G p.L377V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1288503017, COSV59188438; called by mutect2, varscan2
- ASTN2 | c.2829G>C p.K943N (on ENST00000313400 / NM_001365069.1; = p.K892N on NM_014010.5) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.129); catalogued as COSV56004743; called by muse, mutect2, varscan2
- ATM | c.5113G>A p.D1705N | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs1565474013, COSV53744201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATMIN | c.2119G>C p.D707H | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55146093, COSV55146511; called by muse, mutect2, varscan2
- ATP11A | c.2243G>A p.G748E | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.033); catalogued as COSV99367102; called by muse, mutect2
- ATP2B2 | c.3343G>A p.G1115S (on ENST00000352432; = p.G1081S on NM_001683.5) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59496446; called by muse, mutect2, varscan2
- ATP8B4 | c.3368C>G p.S1123* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV52718791, COSV99462831; called by muse, mutect2, varscan2
- ATRN | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.165); catalogued as rs749496294, COSV53527825; called by muse, mutect2, varscan2
- ATXN7 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55750067; called by muse, mutect2, varscan2
- BAG5 | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV54571093; called by muse, mutect2, varscan2
- BBX | c.2068G>C p.D690H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV57884617; called by muse, mutect2, varscan2
- BCAR3 | c.1274C>G p.S425* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99550016; called by muse, mutect2, varscan2
- BCL9 | c.3796C>T p.P1266S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as COSV52344309; called by mutect2, varscan2
- BCR | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); catalogued as rs545230412, COSV59931129; called by muse, mutect2, varscan2
- BDP1 | c.490-1G>A p.X164_splice | Splice Site (SNP) | VAF 5/61 reads (8%) | catalogued as COSV62431386; called by muse, mutect2
- BEND2 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.192); catalogued as COSV66215826; called by muse, mutect2, varscan2
- BHLHE40 | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56575540; called by muse, mutect2, varscan2
- BIRC2 | c.1173G>A p.M391I | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV57161442; called by muse, mutect2, varscan2
- BOD1L1 | c.5347G>A p.D1783N | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1284934294, COSV50013253; called by muse, mutect2, varscan2
- BRD2 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); catalogued as rs757289131, COSV66373316; called by muse, mutect2, varscan2
- BTRC | c.1723G>A p.D575N (on ENST00000370187 / NM_033637.4; = p.D539N on NM_003939.5) | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs1249182469, COSV64579564; called by muse, mutect2, varscan2
- C11orf71 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV100348239; called by muse, mutect2, varscan2
- C12orf71 | c.229C>G p.Q77E | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV101460494; called by muse, mutect2
- C1orf87 | c.1555C>G p.Q519E | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV64597130; called by muse, mutect2, varscan2
- C20orf194 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52695927; called by muse, mutect2, varscan2
- C2CD3 | c.5788C>T p.L1930F | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.136); catalogued as COSV58093067; called by muse, mutect2, varscan2
- C2orf16 | c.5123G>A p.R1708K | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.14); catalogued as rs1418401799, COSV62673693, COSV62675606; called by muse, mutect2, varscan2
- CA10 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs772993232, COSV53345738; called by muse, mutect2, varscan2
- CA2 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53406807; called by muse, mutect2, varscan2
- CA5B | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59416473; called by muse, mutect2, varscan2
- CACNA1A | c.669G>A p.M223I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV64198086; called by muse, mutect2, varscan2
- CACNA2D1 | c.3169G>C p.D1057H (on ENST00000356253 / NM_001366867.1; = p.D1045H on NM_000722.4) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.789); catalogued as COSV62379698; called by muse, mutect2, varscan2
- CAMK2A | c.992C>T p.S331L (on ENST00000348628 / NM_171825.2; = p.S342L on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as rs1292054661, COSV62246397; called by muse, mutect2, varscan2
- CAMKV | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV56555338, COSV56555401; called by muse, mutect2
- CARS2 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV99959299; called by muse, mutect2, varscan2
- CASQ1 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV63624155; called by muse, mutect2, varscan2
- CBLB | c.2776G>C p.E926Q | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.398); catalogued as COSV51426744, COSV51431714; called by muse, mutect2, varscan2
- CCDC144A | c.3907G>T p.E1303* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100138230; called by muse, mutect2
- CCDC15 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV61081807, COSV61082565; called by muse, mutect2, varscan2
- CCDC180 | c.2345G>C p.G782A | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63830143, COSV63831813; called by muse, mutect2, varscan2
- CCDC73 | c.2894C>T p.P965L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as COSV58798632; called by muse, mutect2, varscan2
- CCDC88A | c.3862G>C p.E1288Q | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.258); catalogued as COSV99709539; called by muse, mutect2
- CCIN | c.657C>G p.F219L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0.095); catalogued as COSV100631842, COSV58724663; called by muse, mutect2, varscan2
- CD2BP2 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV59767989, COSV59769054, COSV59769344; called by muse, mutect2, varscan2
- CD80 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV51802268; called by muse, mutect2, varscan2
- CDC37 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.76); catalogued as COSV55768338; called by muse, mutect2
- CDH19 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV50958996; called by muse, mutect2, varscan2
- CDK11A | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs1171761951, COSV62265380; called by muse, mutect2, varscan2
- CELF2 | c.30G>A p.M10I | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.091); catalogued as COSV64930189; called by muse, mutect2, varscan2
- CENPO | c.479C>G p.P160R | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1345903140, COSV53167534; called by muse, mutect2, varscan2
- CEP128 | c.2833G>C p.D945H | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV55370633; called by muse, mutect2, varscan2
- CEP192 | c.2696C>G p.S899* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as rs1224610157, COSV100380961, COSV58072641; called by muse, mutect2, varscan2
- CEP250 | c.6264G>C p.E2088D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV61170107; called by muse, mutect2, varscan2
- CEP63 | c.1849C>G p.L617V | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV59676346; called by muse, mutect2
- CEP85 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV53329373; called by muse, mutect2, varscan2
- CERCAM | c.1655C>A p.S552Y | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100863781, COSV65711988; called by muse, mutect2
- CGN | c.1165C>G p.Q389E | Missense Mutation (SNP) | VAF 108/199 reads (54%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV54969961; called by muse, mutect2, varscan2
- CHD1 | c.2812C>G p.Q938E | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52340270; called by muse, mutect2, varscan2
- CHD2 | c.1349C>G p.S450* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100560424; called by muse, mutect2, varscan2
- CHFR | c.937G>A p.D313N (on ENST00000432561 / NM_001161345.1; = p.D272N on NM_018223.2) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV57171873; called by muse, mutect2, varscan2
- CHKA | c.872C>A p.S291* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99693849; called by muse, mutect2, varscan2
- CHRDL1 | c.362T>C p.L121P (on ENST00000372045; = p.L127P on NM_145234.4) | Missense Mutation (SNP) | VAF 105/185 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV54325216; called by muse, mutect2, varscan2
- CHRNB1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs202080837, COSV53438818; called by muse, mutect2, varscan2
- CHST4 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV58297106, COSV58297141; called by muse, mutect2, varscan2
- CHST8 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371114438, COSV52858861; called by muse, mutect2, varscan2
- CIB3 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV54166272; called by muse, mutect2, varscan2
- CLASP2 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV100222290; called by muse, mutect2
- CLEC4D | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.26); catalogued as COSV100223084, COSV55228953; called by muse, mutect2
- CLIP1 | c.1705G>C p.E569Q (on ENST00000620786 / NM_001247997.1; = p.E558Q on NM_002956.2) | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV56796871, COSV56801808; called by muse, mutect2, varscan2
- CLUH | c.3884C>T p.S1295F (on ENST00000435359; = p.S1334F on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.485); catalogued as rs1447749888, COSV70928678; called by mutect2, varscan2
- CLUL1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as rs527661052, COSV58111689; called by muse, mutect2, varscan2
- CMYA5 | c.9488G>A p.G3163E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs769260361, COSV71405900; called by muse, mutect2, varscan2
- CNTROB | c.781C>G p.Q261E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs759220534, COSV58050247; called by muse, mutect2, varscan2
- COL11A1 | c.4405G>T p.E1469* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV100614372, COSV62178813; called by muse, mutect2, varscan2
- COL14A1 | c.4544G>T p.G1515V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52854450; called by muse, mutect2, varscan2
- COL1A2 | c.3367C>T p.R1123C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs765271962, COSV51958062, COSV51959307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.7133C>T p.S2378F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs1411532691, COSV60395285; called by muse, varscan2
- COLGALT2 | c.675G>C p.K225N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.313); catalogued as COSV62299316; called by muse, varscan2
- COPS3 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV52005304; called by muse, mutect2
- CORO6 | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV61470862; called by muse, mutect2, varscan2
- CPA2 | c.1127C>G p.S376* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99743650; called by muse, mutect2, varscan2
- CPOX | c.1011C>G p.I337M | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51638380; called by muse, mutect2
- CPSF1 | c.790G>C p.D264H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62940193; called by muse, mutect2, varscan2
- CRAT | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.078); catalogued as rs780641174, COSV58877056; called by muse, mutect2, varscan2
- CSKMT | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.194); catalogued as COSV63473029; called by muse, mutect2, varscan2
- CSMD3 | c.3620C>G p.S1207* (on ENST00000297405 / NM_001363185.1; = p.S1103* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99820585; called by muse, mutect2, varscan2
- CTTN | c.1569G>C p.E523D | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV57232351; called by muse, mutect2, varscan2
- CYP26B1 | c.1144G>C p.D382H | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99134166; called by muse, mutect2
- CYP2F1 | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV58527458, COSV58528048; called by muse, mutect2, varscan2
- CYP4Z1 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.9); catalogued as COSV100497467; called by muse, mutect2, varscan2
- DAXX | c.186G>C p.E62D | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV56469312; called by muse, mutect2, varscan2
- DDX11 | c.2258C>G p.S753C (on ENST00000545668 / NM_152438.2; = p.S703C on NM_004399.3) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52504212; called by muse, mutect2, varscan2
- DDX3X | c.1213G>T p.G405* (on ENST00000399959; = p.G406* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | catalogued as COSV67863510; called by muse, mutect2
- DDX58 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.101); catalogued as COSV65883191; called by muse, mutect2, varscan2
- DHX15 | c.281C>G p.S94* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV61025336; called by muse, mutect2, varscan2
- DIMT1 | c.417C>G p.F139L | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52233680; called by muse, varscan2
- DIP2B | c.3246G>C p.Q1082H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV56583967; called by muse, mutect2, varscan2
- DLEC1 | c.2149G>C p.E717Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); catalogued as COSV57299723; called by muse, mutect2, varscan2
- DMXL1 | c.2585G>T p.G862V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1400905684, COSV60711488; called by muse, mutect2, varscan2
- DNAH17 | c.3358G>A p.D1120N | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV67754392; called by muse, mutect2, varscan2
- DNAH7 | c.8360C>G p.S2787C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765064; called by muse, mutect2, varscan2
- DNAH9 | c.10963G>C p.E3655Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as COSV52349728; called by muse, mutect2, varscan2
- DNAJC13 | c.1339C>G p.Q447E | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV53450042; called by muse, mutect2
- DOP1B | c.6826G>C p.D2276H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as COSV67690766; called by muse, mutect2, varscan2
- DSP | c.6279C>G p.I2093M | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV65792722, COSV65792749; called by muse, mutect2, varscan2
- DSP | c.7541C>G p.S2514C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV65792468, COSV65792760; called by muse, mutect2, varscan2
- DVL2 | c.882C>G p.I294M | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50035967; called by muse, mutect2, varscan2
- ECI2 | c.672G>A p.L224= (on ENST00000380118 / NM_206836.3; = p.L194= on NM_006117.2) | Splice Region (SNP) | VAF 6/30 reads (20%) | catalogued as COSV60986482; called by muse, mutect2, varscan2
- EDA | c.872G>C p.G291A | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65781410; called by muse, mutect2, varscan2
- EDC4 | c.2629G>C p.E877Q | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100197385; called by muse, mutect2
- EDC4 | c.2802G>A p.M934I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59302730, COSV59303780; called by muse, mutect2, varscan2
- EEA1 | c.4140C>G p.I1380M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59285817; called by muse, mutect2, varscan2
- EEF1B2 | c.304G>C p.D102H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51909644; called by muse, mutect2, varscan2
- EFS | c.1425G>C p.K475N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52835614; called by muse, mutect2, varscan2
- EGF | c.1877C>G p.S626C | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV54478830; called by muse, mutect2, varscan2
- EIF2S1 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV53605296; called by muse, mutect2, varscan2
- EIF4B | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100016583; called by muse, mutect2, varscan2
- EIF4E2 | c.200G>C p.R67T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV51471920; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.542G>C p.R181T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV57516048; called by muse, mutect2, varscan2
- ERBB2 | c.3622C>T p.H1208Y | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.112); catalogued as COSV54068464; called by muse, mutect2, varscan2
- ERBB3 | c.2851G>A p.D951N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57253340, COSV57261713; called by muse, varscan2
- ERBB3 | c.2943G>C p.E981D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57253360; called by muse, mutect2, varscan2
- ERBB4 | c.1593C>G p.I531M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV53532835; called by mutect2, varscan2
- ERC1 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100705541; called by muse, mutect2, varscan2
- ERCC6 | c.3273G>C p.L1091F | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV63390088; called by muse, mutect2, varscan2
- ESYT2 | c.1414C>T p.L472F (on ENST00000613624; = p.L396F on NM_020728.3) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.464); catalogued as COSV51750979, COSV51753474; called by muse, mutect2, varscan2
- EXOC2 | c.2120C>T p.S707L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57865097; called by muse, mutect2, varscan2
- EXTL1 | c.1096C>G p.L366V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV65337563; called by muse, mutect2, varscan2
- F5 | c.4224G>C p.Q1408H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV63123892; called by muse, mutect2, varscan2
- FAM155A | c.625A>G p.S209G | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101026178; called by muse, mutect2
- FAM186B | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57721532; called by muse, mutect2, varscan2
- FAM216A | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV66600302; called by muse, mutect2, varscan2
- FAM53B | c.347C>A p.S116* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as COSV99784771; called by muse, mutect2, varscan2
- FANCA | c.1890G>C p.E630D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs748122887, COSV101224637; called by muse, mutect2
- FAT1 | c.2881C>T p.Q961* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as COSV101498593; called by muse, mutect2, varscan2
- FAT3 | c.4534G>C p.D1512H | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV53110298, COSV99962258; called by muse, mutect2, varscan2
- FBN3 | c.1286C>A p.S429Y | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV54460614; called by muse, mutect2, varscan2
- FBXO22 | c.747C>G p.I249M | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV57617466; called by muse, mutect2, varscan2
- FBXO34 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100571799; called by muse, mutect2
- FBXW10 | c.159G>C p.Q53H | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV100111120; called by muse, mutect2, varscan2
- FKBP15 | c.3043G>C p.E1015Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV53034811, COSV99440070; called by muse, mutect2, varscan2
- FLG | c.6320C>G p.S2107C | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV64241840; called by muse, varscan2
- FLG | c.4607G>C p.G1536A | Missense Mutation (SNP) | VAF 49/344 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.169); catalogued as COSV64241842; called by muse, mutect2, varscan2
- FLG2 | c.2578C>T p.Q860* | Nonsense Mutation (SNP) | VAF 74/427 reads (17%) | catalogued as COSV101165532; called by muse, mutect2, varscan2
- FLVCR2 | c.336C>G p.F112L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV53162333, COSV99471323; called by muse, mutect2, varscan2
- FMN2 | c.1332G>C p.K444N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs571454130, COSV60427813; called by muse, mutect2, varscan2
- FNBP4 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as COSV55448664, COSV55452718; called by muse, mutect2, varscan2
- FNDC1 | c.5231C>T p.S1744L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369189702; called by muse, mutect2, varscan2
- FNDC3B | c.1700C>T p.T567M | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs149280961; called by muse, mutect2, varscan2
- FRK | c.1101C>G p.I367M | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.695); catalogued as COSV73383981; called by muse, mutect2, varscan2
- FRMPD1 | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV66700420, COSV66700643; called by muse, mutect2, varscan2
- GABRB2 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs140795978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAK | c.3559C>G p.Q1187E | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1226169420, COSV58504762; called by muse, mutect2, varscan2
- GBA | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV100516368, COSV59169753; called by muse, mutect2, varscan2
- GDPD5 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs553455165, COSV61126789, COSV61127626; called by muse, mutect2, varscan2
- GJA8 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 57/112 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53788916, COSV99569142; called by muse, mutect2, varscan2
- GLB1L | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.135); catalogued as COSV55476601; called by muse, mutect2, varscan2
- GLI2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs774865060, COSV58042044; called by muse, mutect2, varscan2
- GLIS3 | c.1512G>T p.R504S | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV60928999; called by muse, mutect2, varscan2
- GMPPA | c.604C>G p.Q202E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV100354423; called by muse, mutect2
- GPATCH3 | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64651496, COSV64652080; called by muse, mutect2
- GPD1L | c.309C>G p.I103M | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV56990078; called by muse, mutect2, varscan2
- GPHN | c.1712C>T p.S571L (on ENST00000315266 / NM_001377519.1; = p.S604L on NM_020806.5) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59473477; called by muse, mutect2, varscan2
- GREB1 | c.3536C>T p.P1179L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV52197809; called by muse, mutect2, varscan2
- GRK2 | c.723C>G p.I241M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.718); catalogued as COSV57951841; called by muse, mutect2, varscan2
- GRM5 | c.1954G>T p.G652C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs758198713, COSV59605237; called by muse, mutect2, varscan2
- GRM7 | c.1275G>A p.M425I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV63143356; called by muse, mutect2, varscan2
- GUCY2C | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.03); catalogued as rs762254572, COSV53790214; called by muse, mutect2, varscan2
- H1-2 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1459637809, COSV59189564, COSV59190422; called by muse, mutect2, varscan2
- H3-3B | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 28/69 reads (41%) | catalogued as COSV54666696, COSV54666887; called by muse, mutect2, varscan2
- H3C11 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); catalogued as rs772596697, COSV58900048; called by muse, mutect2, varscan2
- HAND1 | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50562631; called by muse, mutect2, varscan2
- HAUS6 | c.2359C>G p.L787V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.303); catalogued as COSV65839996; called by muse, mutect2, varscan2
- HCAR2 | c.75C>G p.F25L | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV61024858, COSV61024889; called by muse, mutect2, varscan2
- HELZ | c.2263C>G p.Q755E | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as COSV62378503; called by muse, mutect2, varscan2
- HERC2 | c.4342G>A p.E1448K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.027); catalogued as COSV55323725; called by muse, mutect2, varscan2
- HIPK3 | c.1283A>G p.K428R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV57562565; called by muse, mutect2, varscan2
- HIVEP1 | c.5899G>A p.D1967N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.105); catalogued as COSV65101431; called by muse, mutect2, varscan2
- HMCN1 | c.2989C>G p.P997A | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV54900698; called by muse, mutect2, varscan2
- HTR7 | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.494); catalogued as COSV53286620; called by muse, mutect2, varscan2
- ICMT | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as rs1426915192, COSV100658185; called by muse, mutect2, varscan2
- IFI16 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99856807; called by muse, mutect2
- IFI16 | c.1019G>C p.R340T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55534029; called by muse, mutect2, varscan2
- IFNW1 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | catalogued as COSV101207585; called by muse, mutect2, varscan2
- IGFBP1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV51874719; called by muse, mutect2, varscan2
- IGLON5 | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54535849; called by muse, mutect2, varscan2
- IGLV5-45 | c.89C>G p.S30C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761763804; called by muse, mutect2, varscan2
- IHO1 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56507724; called by muse, varscan2
- IMPG2 | c.3310A>G p.I1104V | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1373143398, COSV51978278; called by muse, mutect2, varscan2
- IQCB1 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60437485; called by muse, mutect2
- IQSEC3 | c.2100G>A p.M700I (on ENST00000538872 / NM_001170738.2; = p.M397I on NM_015232.1) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV58284896; called by muse, mutect2, varscan2
- ISL1 | c.711G>C p.K237N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57933604; called by muse, mutect2, varscan2
- ITGB4 | c.2966G>C p.R989T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV52325893; called by muse, mutect2, varscan2
- ITLN1 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as COSV58275117; called by muse, mutect2, varscan2
- JMJD1C | c.6409G>C p.E2137Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.134); catalogued as COSV59514893; called by muse, mutect2, varscan2
- KAT7 | c.227G>C p.R76T | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV52014520; called by muse, mutect2, varscan2
- KCNA1 | c.1345A>C p.M449L | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66837358; called by muse, mutect2, varscan2
- KCNB1 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.124); catalogued as COSV65568264; called by muse, mutect2, varscan2
- KCNJ3 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as rs951927978, COSV99715026; called by muse, mutect2, varscan2
- KCTD20 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); catalogued as COSV54803221; called by muse, mutect2, varscan2
- KDM4A | c.1370C>G p.S457C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV64959562; called by muse, mutect2, varscan2
- KDM4C | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67186509; called by muse, mutect2, varscan2
- KIF24 | c.1901G>C p.R634T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV61454642; called by muse, mutect2, varscan2
- KLHL8 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV56747822; called by muse, varscan2
- KLHL8 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV56747834; called by muse, varscan2
- KLK10 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as rs760434630, COSV100010816; called by muse, varscan2
- KMT2A | c.9710C>G p.S3237C | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV63285768; called by muse, mutect2, varscan2
- KMT2C | c.13228G>A p.D4410N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51428348, COSV51439628; called by muse, mutect2, varscan2
- KMT2C | c.5234C>G p.S1745* | Nonsense Mutation (SNP) | VAF 30/137 reads (22%) | catalogued as COSV51425691, COSV51466439, COSV51467394; called by muse, mutect2, varscan2
- KMT2D | c.8082G>C p.Q2694H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV56439615; called by muse, mutect2, varscan2
- KMT2D | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.262); catalogued as COSV56439636; called by muse, mutect2, varscan2
- KMT2D | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV99976450, COSV99977213; called by muse, mutect2, varscan2
- KRT13 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55839967, COSV55840970; called by muse, mutect2, varscan2
- KRT23 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99266076, COSV99266385; called by muse, mutect2, varscan2
- KRT33B | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs931017212, COSV52440908; called by muse, mutect2, varscan2
- KRT34 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV67449820; called by muse, mutect2
- L3MBTL2 | c.2089G>T p.E697* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV99345541; called by muse, mutect2, varscan2
- LONP1 | c.1905C>G p.F635L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs746046624, COSV61501834; called by muse, mutect2, varscan2
- LRBA | c.3802C>G p.Q1268E | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as COSV63955523; called by muse, mutect2
- LRCH1 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs761448015, COSV60847410; called by muse, mutect2, varscan2
- LRIG2 | c.2462C>G p.S821C | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1024335273, COSV63162158; called by muse, mutect2, varscan2
- LRP1B | c.11239G>A p.D3747N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV67211484, COSV67220404; called by muse, mutect2, varscan2
- LRP1B | c.9778G>C p.D3260H | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV67203879, COSV67220409; called by muse, mutect2, varscan2
- LRP2 | c.3901G>A p.D1301N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55553236; called by muse, mutect2, varscan2
- LRP2 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV55553248; called by muse, mutect2, varscan2
- LRP2 | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55553255; called by muse, mutect2, varscan2
- LRRC15 | c.1552C>G p.L518V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.17); catalogued as COSV61650125; called by muse, mutect2, varscan2
- LRRCC1 | c.1442G>A p.R481K | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781161064, COSV64483445; called by muse, mutect2, varscan2
- LSG1 | c.1394G>C p.R465T | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54570203, COSV54570980; called by muse, mutect2, varscan2
- LZTFL1 | c.72G>C p.K24N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.377); catalogued as COSV56111448; called by muse, mutect2, varscan2
- MACF1 | c.20279G>A p.R6760Q (on ENST00000372915; = p.R4805Q on NM_012090.5) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as rs1399990361, COSV57121176; called by muse, mutect2, varscan2
- MAP2K4 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.115); catalogued as rs1355543573, COSV62257347; called by muse, mutect2, varscan2
- MAP3K13 | c.2578G>C p.E860Q | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53984006, COSV53988707; called by muse, mutect2, varscan2
- MAP3K2 | c.1541C>G p.S514* | Nonsense Mutation (SNP) | VAF 35/131 reads (27%) | catalogued as rs1313569240, COSV100789239; called by muse, mutect2, varscan2
- MARCHF7 | c.86G>A p.R29K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.373); catalogued as rs1176285723, COSV52028843; called by muse, mutect2, varscan2
- MAST2 | c.420G>C p.M140I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.041); catalogued as COSV63618235; called by muse, mutect2, varscan2
- MBD2 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 30/127 reads (24%) | catalogued as COSV99839759; called by muse, mutect2, varscan2
- MCM10 | c.1547C>G p.S516C (on ENST00000484800 / NM_182751.3; = p.S515C on NM_018518.5) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66334392; called by muse, mutect2, varscan2
- MECOM | c.718G>A p.E240K (on ENST00000468789 / NM_001105078.4; = p.E428K on NM_004991.4) | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52964419; called by muse, varscan2
- MED24 | c.1338G>C p.K446N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV62418644; called by muse, mutect2, varscan2
- MEGF11 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.287); catalogued as COSV99986622; called by muse, mutect2
- MEGF8 | c.5669G>C p.G1890A (on ENST00000251268 / NM_001271938.2; = p.G1823A on NM_001410.3) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.94); catalogued as COSV52076061, COSV52084693; called by muse, mutect2, varscan2
- MEIOC | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0.154); catalogued as rs943452853, COSV63440142, COSV63441638; called by muse, mutect2, varscan2
- MICAL2 | c.5802C>G p.I1934M | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV56285909; called by muse, mutect2, varscan2
- MKI67 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64073928, COSV64074350; called by muse, mutect2, varscan2
- MLXIPL | c.2393C>G p.S798* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100515127; called by muse, mutect2, varscan2
- MPDZ | c.4151G>C p.G1384A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100055952; called by muse, mutect2
- MR1 | c.1002C>G p.I334M | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV51580860; called by muse, mutect2, varscan2
- MROH2B | c.1013G>C p.R338T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV68184089, COSV68185594; called by muse, mutect2, varscan2
- MTARC2 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as rs769610751, COSV100830829; called by muse, varscan2
- MTHFD1 | c.137G>C p.R46T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV53700380; called by muse, mutect2, varscan2
- MTMR12 | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.335); catalogued as COSV99373279; called by muse, mutect2
- MTREX | c.1513G>C p.D505H | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57924143, COSV57924570; called by muse, mutect2, varscan2
- MTURN | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100188672; called by muse, mutect2, varscan2
- MUC16 | c.37735C>G p.L12579V | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.352); catalogued as COSV67465934; called by muse, mutect2, varscan2
- MUC16 | c.30410C>G p.S10137C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV67465936; called by muse, mutect2, varscan2
- MUC16 | c.27887C>G p.S9296C | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.85); catalogued as rs866520533, COSV67465938, COSV67497215; called by muse, mutect2, varscan2
- MUC16 | c.21719C>G p.S7240* | Nonsense Mutation (SNP) | VAF 44/155 reads (28%) | catalogued as COSV101197345; called by muse, mutect2, varscan2
- MUC17 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.093); catalogued as COSV60288530; called by muse, mutect2, varscan2
- MYCBP2 | c.4417G>T p.E1473* (on ENST00000357337; = p.E1511* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | catalogued as COSV100628834, COSV100630229; called by muse, mutect2, varscan2
- MYF5 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.87); catalogued as rs1386326579, COSV57355110, COSV99079021; called by muse, mutect2
- MYH10 | c.5119G>A p.E1707K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.418); catalogued as rs199665530, COSV52600582; called by muse, mutect2, varscan2
- MYT1L | c.2555G>C p.R852T | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV101221039, COSV67720367; called by muse, mutect2
- NAV2 | c.5841G>C p.E1947D (on ENST00000396087 / NM_001244963.2; = p.E1888D on NM_145117.5) | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.956); catalogued as COSV60659392; called by muse, mutect2, varscan2
- NCKAP5 | c.3874G>T p.E1292* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100489348; called by muse, mutect2, varscan2
- NCOR1 | c.4181C>G p.S1394* | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | catalogued as COSV51962844; called by muse, mutect2, varscan2
- NDST3 | c.2359C>G p.L787V | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56619038; called by muse, mutect2, varscan2
- NDUFA8 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65653399; called by muse, mutect2, varscan2
- NEB | c.134C>A p.S45* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99413462; called by muse, mutect2
- NEIL3 | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52810448; called by mutect2, varscan2
- NETO1 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100197997; called by muse, mutect2, varscan2
- NFATC1 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53700358; called by muse, mutect2, varscan2
- NFKBIA | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as COSV53751744, COSV53752537, COSV53753434; called by muse, mutect2, varscan2
- NHLRC1 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as rs771805307, COSV61481228, COSV61481289; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLGN4Y | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV52970062; called by muse, mutect2, varscan2
- NLRP1 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs748825605, COSV52566292; called by muse, mutect2, varscan2
- NLRP10 | c.1653G>C p.Q551H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs144039243, COSV60781726; called by muse, mutect2, varscan2
- NOA1 | c.1393G>C p.D465H | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV51737012; called by muse, mutect2
- NOMO1 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.628); catalogued as rs373446176; called by muse, mutect2, varscan2
- NOP56 | c.1443G>C p.K481N | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1278613914, COSV61389997; called by muse, mutect2
- NOVA2 | c.1443G>C p.Q481H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV54357311; called by muse, mutect2, varscan2
- NRDE2 | c.846G>A p.W282* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as rs1566693313, COSV100583168; called by muse, mutect2, varscan2
- NRROS | c.775C>G p.H259D | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.091); catalogued as COSV100145300; called by muse, mutect2
- NSMCE3 | c.633G>C p.K211N | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV54271374, COSV99721152; called by muse, mutect2, varscan2
- NUCB1 | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV54386281; called by muse, mutect2, varscan2
- NUCB1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs1568588707, COSV54386290; called by muse, mutect2, varscan2
- NUP188 | c.4735C>G p.Q1579E | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100999315; called by muse, mutect2
- NUP210L | c.1876C>G p.L626V | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV55146489, COSV55147569; called by muse, mutect2, varscan2
- NUP214 | c.6123G>C p.Q2041H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63909603; called by muse, mutect2
- NUP98 | c.2924C>T p.S975F (on ENST00000359171 / NM_001365126.1; = p.S958F on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs11607340, COSV61432269; called by muse, mutect2, varscan2
- NXF1 | c.1813C>G p.H605D | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV53674108; called by muse, mutect2, varscan2
- OGFOD1 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV60200613; called by muse, mutect2, varscan2
- OIT3 | c.136C>G p.Q46E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV61826121; called by muse, mutect2, varscan2
- OIT3 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV61826138; called by muse, mutect2, varscan2
- OPLAH | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV101470691, COSV101470743; called by muse, mutect2, varscan2
- OPRD1 | c.725G>C p.S242T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV52381918; called by muse, mutect2, varscan2
- OR4F6 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV61026377; called by muse, mutect2, varscan2
- OR5D14 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1275547604, COSV59456301; called by muse, mutect2, varscan2
- OR8K3 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57131531; called by muse, mutect2, varscan2
- OR8S1 | c.791C>G p.S264* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as rs764732510, COSV100043420, COSV100043685; called by muse, mutect2, varscan2
- OSBPL8 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV53882551; called by muse, mutect2, varscan2
- OTUD7B | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100967282; called by muse, mutect2, varscan2
- PABPC1 | c.1872G>C p.Q624H | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.167); catalogued as COSV59401682; called by muse, mutect2, varscan2
- PABPC4 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs141523814; called by muse, mutect2, varscan2
- PAH | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs62642938, CM961063, COSV61016517; ClinVar: not provided; called by muse, mutect2, varscan2
- PAK1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53696532; called by muse, mutect2, varscan2
- PAK2 | c.34C>G p.P12A | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV59081277; called by muse, mutect2
- PAPPA2 | c.3265T>G p.Y1089D | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62797675; called by muse, mutect2, varscan2
- PCDH15 | c.4345G>A p.E1449K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); catalogued as COSV57311818; called by muse, mutect2, varscan2
- PCDHAC1 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.19); catalogued as COSV53849268; called by muse, mutect2, varscan2
- PCDHB8 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782519470, COSV50767909; called by muse, mutect2, varscan2
- PCID2 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.041); catalogued as rs375098990; called by muse, mutect2, varscan2
- PDE10A | c.2299C>G p.R767G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs141939882, COSV63096689, COSV63099141; called by muse, mutect2, varscan2
- PEG3 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV55633491; called by muse, mutect2, varscan2
- PIAS2 | c.1402G>C p.D468H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV61343290; called by muse, mutect2, varscan2
- PIFO | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV63863821; called by muse, mutect2, varscan2
- PIFO | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63863825; called by muse, mutect2, varscan2
- PIGO | c.1156C>G p.Q386E | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.17); catalogued as COSV53053686; called by muse, mutect2, varscan2
- PIK3CG | c.2650G>C p.D884H | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as COSV100782974, COSV63247316, COSV63248596; called by muse, mutect2, varscan2
- PITPNM2 | c.2911G>T p.E971* | Nonsense Mutation (SNP) | VAF 31/180 reads (17%) | catalogued as COSV54895353, COSV99758061; called by muse, mutect2, varscan2
- PKD2L1 | c.1273T>G p.Y425D | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58396047; called by muse, mutect2
- PLEKHG4 | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0.146); catalogued as rs200287373, COSV58572908; called by muse, mutect2, varscan2
- PLEKHG4B | c.2380G>A p.E794K (on ENST00000283426; = p.E1150K on NM_052909.5) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV99359575; called by muse, mutect2, varscan2
- PLS1 | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as rs1159813614, COSV61833603; called by muse, mutect2, varscan2
- PNP | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV64091967; called by muse, mutect2, varscan2
- PNP | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV64091968; called by muse, mutect2, varscan2
- PNPLA7 | c.306G>C p.K102N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV52998801, COSV53006014; called by muse, mutect2, varscan2
- POGLUT2 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1231592875, COSV65683087; called by muse, mutect2, varscan2
- PPARG | c.929T>C p.F310S (on ENST00000287820 / NM_015869.5; = p.F280S on NM_005037.7) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55142447; called by muse, mutect2, varscan2
- PPFIA2 | c.3604C>T p.P1202S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61027363; called by muse, mutect2, varscan2
- PPIF | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as rs747434200, COSV56551206; called by muse, mutect2, varscan2
- PPP6R1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as rs1212380870, COSV69799734; called by muse, mutect2
- PREX2 | c.2026G>C p.E676Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs1352854335, COSV55757424, COSV55771428; called by muse, mutect2
- PRKCB | c.320A>G p.H107R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); catalogued as COSV57779883; called by muse, mutect2, varscan2
- PRPF40A | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.794); catalogued as COSV62957635; called by muse, mutect2
- PSMA6 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV54837723, COSV54838972; called by muse, mutect2, varscan2
- PSPC1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV58887991; called by muse, mutect2, varscan2
- PTPN2 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100518234; called by muse, mutect2, varscan2
- PTPRM | c.2168G>A p.G723E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59859035; called by muse, mutect2, varscan2
- PTPRS | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.523); catalogued as rs1383575470, COSV53619678; called by muse, mutect2, varscan2
- PUS7L | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61261871; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1387C>G p.Q463E | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV62783957; called by muse, mutect2, varscan2
- RASGEF1B | c.855G>T p.M285I | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV52337131; called by muse, mutect2, varscan2
- RASGRF1 | c.3527G>C p.R1176T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60212641; called by muse, mutect2, varscan2
- RB1 | c.2678G>C p.G893A | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.021); catalogued as COSV57307412; called by mutect2, varscan2
- RBM12B | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV67897967; called by muse, varscan2
- RBM12B | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV66968153; called by muse, mutect2, varscan2
- RBM12B | c.1000C>G p.L334V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.675); catalogued as COSV66968155; called by muse, mutect2
- RBM12B | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.144); catalogued as COSV66968157; called by muse, mutect2, varscan2
- RBM19 | c.1440C>G p.I480M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as COSV55692215; called by muse, mutect2, varscan2
- RC3H1 | c.996G>C p.Q332H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51200824; called by muse, mutect2, varscan2
- RCL1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1422086276, COSV67754126; called by muse, mutect2, varscan2
- RHBDF2 | c.2134C>T p.L712F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51684640; called by muse, mutect2, varscan2
- RIF1 | c.4413A>C p.E1471D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.813); catalogued as COSV54617084; called by muse, mutect2, varscan2
- RLF | c.734C>G p.S245* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV101034950; called by muse, mutect2, varscan2
- RNF111 | c.1775G>A p.C592Y | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs776377062, COSV62085965; called by muse, mutect2, varscan2
- RPS6KA6 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53119902; called by muse, mutect2, varscan2
- RRM1 | c.1036C>G p.Q346E | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV56164190; called by muse, mutect2, varscan2
- RTL10 | c.45C>G p.I15M | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV100144235, COSV60735502; called by muse, mutect2, varscan2
- RUVBL1 | c.1165G>T p.E389* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as COSV100493991; called by muse, mutect2
- SACS | c.11005C>G p.Q3669E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as COSV66539952; called by muse, mutect2, varscan2
- SAG | c.882G>C p.R294S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV68591020; called by muse, mutect2
- SARS1 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.56); catalogued as COSV52320798; called by muse, mutect2, varscan2
- SCN3A | c.5077G>C p.E1693Q | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.987); catalogued as COSV51809898; called by muse, mutect2, varscan2
- SDE2 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | catalogued as COSV99682401; called by muse, mutect2, varscan2
- SEC16A | c.3058C>T p.Q1020* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV51544502; called by muse, mutect2, varscan2
- SEC31A | c.615C>G p.I205M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV52345620; called by muse, mutect2
- SERPINB6 | c.1159C>G p.L387V (on ENST00000612421 / NM_001271823.2; = p.L368V on NM_004568.6) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV59565729; called by muse, mutect2, varscan2
- SERPINC1 | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV62929404; called by muse, mutect2
- SERPINE1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs1163437425, COSV56169666; called by muse, mutect2, varscan2
- SERPING1 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs866038065, COSV53542496; called by muse, mutect2, varscan2
- SETD2 | c.7690G>A p.E2564K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.359); catalogued as rs780004717, COSV57437786; called by muse, mutect2, varscan2
- SETD5 | c.3505C>T p.P1169S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1236892221, COSV56710969; called by muse, mutect2, varscan2
- SGSM3 | c.774C>G p.Y258* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99960060; called by muse, mutect2, varscan2
- SHH | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs1201542449, COSV99793200, COSV99793344; called by muse, mutect2
- SIM2 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51768820; called by muse, mutect2, varscan2
- SIX4 | c.608G>C p.G203A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs755306854, COSV53669579; called by muse, mutect2, varscan2
- SIX4 | c.48C>G p.I16M | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV53669585; called by muse, varscan2
- SLC16A6 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as rs782767113, COSV100517138; called by muse, mutect2, varscan2
- SLC2A14 | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV61586305, COSV61586593; called by muse, mutect2, varscan2
- SLC32A1 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs776361290, COSV54145548, COSV99462625; called by muse, mutect2, varscan2
- SLC5A3 | c.1489G>C p.D497H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.854); catalogued as COSV62969779; called by muse, mutect2, varscan2
- SLC6A15 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs759631659, COSV57023803; called by muse, mutect2, varscan2
- SMAD4 | c.1454C>T p.S485L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); catalogued as COSV100747404, COSV61684308; called by muse, mutect2
- SMC4 | c.2505G>C p.L835F | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61004904; called by muse, mutect2
- SMCO3 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV53762931; called by muse, mutect2, varscan2
- SMG8 | c.2889G>C p.E963D | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV56285237, COSV99958931; called by muse, mutect2, varscan2
- SNAI3 | c.286C>G p.R96G | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV60002812; called by muse, mutect2, varscan2
- SNX32 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as COSV57449528; called by muse, mutect2, varscan2
- SOCS6 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as rs768568432, COSV67546398; called by muse, mutect2, varscan2
- SOGA3 | c.2067C>G p.S689R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.832); catalogued as COSV64106558, COSV64108061; called by muse, mutect2, varscan2
- SPAG17 | c.2422G>A p.D808N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV60452444, COSV60458869; called by muse, mutect2, varscan2
- SPATA7 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV50417215, COSV50418401; called by muse, mutect2, varscan2
- SPTAN1 | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as rs1011782482, COSV63985314; called by muse, mutect2, varscan2
- SRCAP | c.4888C>T p.P1630S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.275); catalogued as COSV52672648; called by muse, mutect2, varscan2
- SREBF2 | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.035); catalogued as COSV63331247; called by muse, mutect2, varscan2
- SRSF11 | c.1116G>C p.R372S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV100917761; called by muse, mutect2, varscan2
- ST18 | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.769); catalogued as COSV99387654; called by muse, mutect2
- STBD1 | c.386C>G p.S129C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775774867, COSV52953805; called by muse, mutect2, varscan2
- STK17A | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60047132; called by muse, mutect2, varscan2
- STK31 | c.1831G>C p.E611Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV63456046; called by muse, mutect2, varscan2
- STK38L | c.717G>C p.K239N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV66521460; called by muse, mutect2, varscan2
- SUGP2 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100432342, COSV58258800; called by muse, mutect2, varscan2
- SULF2 | c.1906G>C p.E636Q | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); catalogued as COSV63415968; called by muse, mutect2, varscan2
- SUMO1 | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 42/206 reads (20%) | catalogued as COSV101108577, COSV66260044; called by muse, mutect2, varscan2
- SUPT16H | c.2836G>C p.E946Q | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV52850077; called by muse, mutect2, varscan2
- SWT1 | c.1945G>C p.E649Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62255201; called by muse, mutect2
- SYAP1 | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV66468063; called by muse, mutect2, varscan2
- SYNE1 | c.20997G>C p.M6999I (on ENST00000367255 / NM_182961.4; = p.M6928I on NM_033071.3) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54981747; called by muse, mutect2, varscan2
- SYNE1 | c.1669G>A p.E557K (on ENST00000367255 / NM_182961.4; = p.E564K on NM_033071.3) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54974428, COSV54981787; called by muse, mutect2, varscan2
- SYNJ1 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59148355; called by muse, mutect2, varscan2
- TAOK1 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55591818; called by muse, mutect2, varscan2
- TAS2R39 | c.959G>A p.R320K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as rs1248683026, COSV71470880; called by muse, mutect2, varscan2
- TAX1BP1 | c.2320G>C p.E774Q | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); catalogued as COSV52237784, COSV99033397; called by muse, mutect2, varscan2
- TBC1D5 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV53757169; called by muse, mutect2
- TBRG4 | c.684G>A p.M228I | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV51832677; called by muse, mutect2, varscan2
- TBX4 | c.817A>T p.S273C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV53607117; called by muse, mutect2, varscan2
- TCF25 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1023462901, COSV99642172; called by muse, mutect2, varscan2
- TEKT3 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100106684, COSV58626955; called by muse, mutect2
- TESK1 | c.350G>C p.G117A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52411068; called by muse, mutect2, varscan2
- TESPA1 | c.1147G>C p.D383H (on ENST00000316577 / NM_001098815.3; = p.D245H on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV57258913; called by muse, mutect2, varscan2
- TEX15 | c.2213G>T p.G738V (on ENST00000256246; = p.G1121V on NM_001350162.2) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV56346515; called by muse, mutect2, varscan2
- TGDS | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54300782; called by muse, mutect2, varscan2
- THUMPD3 | c.1459C>G p.Q487E | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV61506004; called by muse, mutect2
- TIAM1 | c.3697G>C p.E1233Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV54551145; called by mutect2, varscan2
- TLR3 | c.2421C>G p.I807M | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.68); catalogued as COSV57167475, COSV57168595, COSV57169136; called by muse, mutect2, varscan2
- TMCC1 | c.1109G>A p.R370K (on ENST00000393238 / NM_001349268.2; = p.R46K on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV100261025, COSV61440523; called by muse, mutect2, varscan2
- TMEM115 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99223389; called by muse, mutect2, varscan2
- TMEM132A | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV50005868; called by muse, mutect2, varscan2
- TMEM132D | c.3097G>A p.E1033K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs768389546, COSV67160428; called by muse, mutect2, varscan2
- TMEM132E | c.1039G>A p.D347N (on ENST00000321639; = p.D437N on NM_001304438.2) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1204451336, COSV58697020; called by muse, mutect2
- TMEM145 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.149); catalogued as COSV56624728; called by muse, mutect2, varscan2
- TMEM65 | c.571C>G p.L191V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1218737871, COSV52630474; called by muse, mutect2, varscan2
- TMPRSS13 | c.38G>C p.R13T | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as COSV101471341; called by muse, mutect2
- TMPRSS5 | c.462C>T p.L154= | Splice Region (SNP) | VAF 12/66 reads (18%) | catalogued as COSV55423668; called by muse, mutect2, varscan2
- TNFRSF10C | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.925); catalogued as COSV63511657; called by muse, mutect2, varscan2
- TNN | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV99510743; called by muse, varscan2
- TNXB | c.6772G>A p.E2258K (on ENST00000647633; = p.E2011K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as rs1434254207, COSV64478989; called by muse, mutect2, varscan2
- TP73 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs749787981, COSV60698569; called by muse, varscan2
- TPRN | c.1787C>G p.S596C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58807475; called by muse, mutect2, varscan2
- TRIM13 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV53949530; called by muse, mutect2, varscan2
- TRPM7 | c.4388C>G p.S1463C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.088); catalogued as COSV100539268; called by muse, mutect2
- TRUB1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.348); catalogued as rs774806190, COSV53929593; called by muse, mutect2, varscan2
- TSPAN9 | c.414G>C p.W138C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99170809; called by muse, mutect2
- TTLL5 | c.3504G>C p.Q1168H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV54033843; called by muse, mutect2
- TTN | c.95908G>A p.E31970K (on ENST00000591111; = p.E24546K on NM_003319.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | PolyPhen possibly damaging (0.766); catalogued as COSV60062449; called by muse, mutect2, varscan2
- TTN | c.18158C>T p.S6053L (on ENST00000591111; = p.S5126L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | PolyPhen benign (0.178); catalogued as COSV60062492; called by muse, mutect2, varscan2
- TTN | c.1419G>C p.K473N | Missense Mutation (SNP) | VAF 13/81 reads (16%) | PolyPhen possibly damaging (0.628); catalogued as COSV60062501; called by muse, mutect2, varscan2
- TUBG1 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV52221190; called by muse, mutect2, varscan2
- UACA | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59855840; called by muse, mutect2, varscan2
- UBA6 | c.1327T>A p.Y443N | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV59177170; called by muse, mutect2, varscan2
- UBAP2 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs142268445; called by muse, mutect2, varscan2
- UBE2T | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV66153329; called by muse, mutect2
- UBR1 | c.2155G>T p.E719* | Nonsense Mutation (SNP) | VAF 36/133 reads (27%) | catalogued as COSV99316436; called by muse, mutect2, varscan2
- UBR3 | c.4505C>G p.S1502C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as COSV55849589, COSV99774690; called by muse, mutect2, varscan2
- UBR5 | c.6937G>C p.E2313Q | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV55286848; called by muse, mutect2, varscan2
- UBXN2A | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100465334, COSV58336485; called by muse, mutect2, varscan2
- UFSP2 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99248766; called by muse, mutect2
- UGGT2 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as COSV65025363; called by muse, mutect2, varscan2
- UNC13C | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as rs565877113, COSV52873149, COSV99509498; called by mutect2, varscan2
- UNC5B | c.1781C>T p.S594L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.083); catalogued as COSV58977231; called by muse, mutect2, varscan2
- UPF3B | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV52230072; called by muse, mutect2, varscan2
- UPP2 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.129); catalogued as COSV50047012, COSV50047745; called by muse, mutect2, varscan2
- UPP2 | c.572A>T p.E191V | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.353); catalogued as COSV50047028; called by muse, mutect2, varscan2
- USP32 | c.2131G>T p.E711* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as COSV100341096, COSV56267657, COSV56279028; called by muse, varscan2
- UTP4 | c.1555C>T p.H519Y | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV58732816; called by muse, mutect2, varscan2
- VARS2 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as rs372389658; called by muse, mutect2, varscan2
- VCAN | c.6908G>A p.R2303K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.014); catalogued as COSV54105111; called by muse, mutect2, varscan2
- VIRMA | c.4921C>T p.Q1641* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as rs1221227749, COSV99887322; called by muse, mutect2, varscan2
- VPS13B | c.3439G>C p.E1147Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100660467; called by muse, mutect2
- VPS13C | c.4988C>G p.S1663C (on ENST00000644861 / NM_020821.3; = p.S1620C on NM_017684.5) | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as COSV51181481; called by muse, mutect2, varscan2
- VPS13D | c.6460G>A p.D2154N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342419323, COSV50638830; called by muse, mutect2, varscan2
- VPS8 | c.2332C>T p.R778W (on ENST00000625842 / NM_001349294.1; = p.R776W on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs774642024, COSV54981333; called by muse, mutect2, varscan2
- VWA8 | c.4383G>C p.K1461N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); catalogued as COSV64996410, COSV64997529; called by muse, mutect2, varscan2
- WASF1 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63935431; called by muse, mutect2, varscan2
- WDR47 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63058081; called by muse, mutect2, varscan2
- WEE1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.093); catalogued as COSV55197210; called by muse, mutect2, varscan2
- WRAP53 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99356334; called by muse, mutect2, varscan2
- ZAN | c.8239C>G p.R2747G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV61809168; called by muse, mutect2, varscan2
- ZC3H14 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs761255138, COSV51769596; called by muse, mutect2, varscan2
- ZC3HAV1 | c.834G>T p.Q278H | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as COSV54295816; called by muse, mutect2, varscan2
- ZEB2 | c.3280G>C p.E1094Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV57953550, COSV57956836; called by muse, mutect2, varscan2
- ZFC3H1 | c.2873C>T p.S958L | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.299); catalogued as COSV66432597; called by muse, mutect2
- ZFHX4 | c.5083C>G p.Q1695E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV50800501; called by muse, mutect2, varscan2
- ZFYVE16 | c.3608-1G>T p.X1203_splice | Splice Site (SNP) | VAF 12/70 reads (17%) | catalogued as COSV62015750; called by muse, mutect2, varscan2
- ZIM3 | c.1237C>T p.H413Y | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1437855488, COSV54142614, COSV54147412; called by muse, mutect2, varscan2
- ZNF112 | c.2000G>C p.C667S (on ENST00000337401 / NM_001083335.2; = p.C661S on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100495637, COSV61619705, COSV61620064; called by muse, mutect2
- ZNF131 | c.438G>C p.K146N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV61002522; called by muse, mutect2, varscan2
- ZNF133 | c.1585C>T p.R529* (on ENST00000316358 / NM_001352454.2; = p.R528* on NM_003434.7 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as rs1182684086, COSV100315235; called by muse, mutect2, varscan2
- ZNF18 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV59551336; called by muse, mutect2, varscan2
- ZNF184 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.541); catalogued as COSV53004304; called by muse, mutect2, varscan2
- ZNF224 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.881); catalogued as rs767394305, COSV61242306; called by muse, mutect2, varscan2
- ZNF232 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as COSV51503435; called by muse, mutect2, varscan2
- ZNF24 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.202); catalogued as rs1569102593, COSV54348559; called by muse, mutect2
- ZNF282 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as rs1174125960, COSV50480082; called by muse, mutect2, varscan2
- ZNF3 | c.806C>G p.S269C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs770084334, COSV52795808; called by muse, mutect2, varscan2
- ZNF33B | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.432); catalogued as rs1458053639, COSV63942565; called by muse, mutect2, varscan2
- ZNF395 | c.146C>G p.S49C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100733875, COSV60428636; called by muse, mutect2, varscan2
- ZNF404 | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV60987301; called by muse, mutect2, varscan2
- ZNF423 | c.3555C>G p.F1185L (on ENST00000563137 / NM_001379286.1; = p.F1177L on NM_015069.4) | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52188835; called by muse, mutect2, varscan2
- ZNF426 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99464866; called by muse, mutect2, varscan2
- ZNF486 | c.694C>G p.H232D | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV58719135; called by muse, mutect2, varscan2
- ZNF536 | c.2407C>T p.R803W | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140147461; called by muse, mutect2, varscan2
- ZNF582 | c.401A>G p.N134S | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV56732125; called by muse, mutect2, varscan2
- ZNF585A | c.1597C>T p.Q533* (on ENST00000292841 / NM_001288800.2; = p.Q478* on NM_152655.3) | Nonsense Mutation (SNP) | VAF 24/114 reads (21%) | catalogued as COSV99492608; called by muse, mutect2, varscan2
- ZNF592 | c.1881C>G p.F627L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV55436905; called by muse, mutect2, varscan2
- ZNF607 | c.397C>G p.Q133E | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV67696881; called by muse, mutect2, varscan2
- ZNF611 | c.764G>C p.G255A | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.22); catalogued as COSV60540859; called by muse, mutect2, varscan2
- ZNF644 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV61347809; called by muse, mutect2, varscan2
- ZNF697 | c.1431C>G p.F477L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.407); catalogued as COSV70284119; called by muse, mutect2, varscan2
- ZNF70 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as rs202042749, COSV100558923, COSV59532795; called by muse, mutect2, varscan2
- ZNF778 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV60601399; called by muse, mutect2, varscan2
- ZNF99 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68055751; called by muse, mutect2, varscan2
- ZSWIM2 | c.1704G>C p.K568N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54575470; called by muse, mutect2, varscan2
- ZWILCH | c.1570C>T p.Q524* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV100328322; called by muse, mutect2, varscan2
- CHD1 | c.2638_2640del p.V880del | In Frame Del (DEL) | VAF 8/30 reads (27%) | called by pindel, varscan2
- DHRS11 | c.756G>C p.Q252H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAAP20 | c.533_534del p.V178Dfs*? | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by pindel, varscan2
- GPR179 | c.4432G>C p.E1478Q (on ENST00000621958; = p.E1477Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- GPR179 | c.3104C>G p.S1035C (on ENST00000621958; = p.S1034C on NM_001004334.4) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKC | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2
- KIR3DL3 | c.281G>C p.R94T | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MRC1 | c.3977C>G p.S1326C | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PIGW | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 29/113 reads (26%) | called by muse, mutect2, varscan2
- PIGW | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PIGW | c.984G>C p.K328N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- PRAMEF19 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 43/315 reads (14%) | called by muse, mutect2, varscan2
- PTGIS | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.927); called by muse, mutect2
- RBM12B | c.1270_1273delinsTTT p.L424Ffs*22 | Frame Shift Del (DEL) | VAF 27/124 reads (22%) | called by pindel, varscan2*
- SUPT16H | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2
- TROAP | c.2251_2252del p.T751Qfs*42 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- ABCD3 | c.99C>A p.L33= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100238647, COSV59868108; called by muse, mutect2
- ABL1 | c.1110G>A p.L370= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV59331593; called by muse, mutect2, varscan2
- ACAA2 | c.1062G>T p.L354= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1010175678, COSV53270793; called by muse, mutect2, varscan2
- ACSL6 | c.678C>T p.L226= (on ENST00000379240; = p.L251= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/178 reads (19%) | catalogued as COSV57298551; called by muse, mutect2, varscan2
- AFF2 | c.3723C>T p.H1241= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV53989550; called by muse, mutect2, varscan2
- AKAP9 | c.9807G>A p.L3269= (on ENST00000359028; = p.L3245= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs753546371, COSV62346368; called by muse, mutect2, varscan2
- AKT3 | c.1107C>T p.L369= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs530726609, COSV55616604; called by muse, mutect2
- ALOX12 | c.841C>T p.L281= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as COSV52349705; called by muse, mutect2, varscan2
- ALPI | c.255G>A p.E85= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1392658218, COSV99785630; called by muse, mutect2, varscan2
- AMIGO3 | c.477C>G p.L159= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV57538590, COSV57539341; called by muse, mutect2, varscan2
- AMN1 | c.414C>G p.L138= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV55671392; called by muse, mutect2, varscan2
- ANKS1B | c.52C>T p.L18= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV61351488; called by muse, mutect2, varscan2
- AOAH | c.549A>G p.K183= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1384702117, COSV51741515; called by muse, mutect2, varscan2
- APPBP2 | c.1757G>A p.*586= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV50028614; called by muse, mutect2, varscan2
- ARHGAP1 | c.367C>T p.L123= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV61734980; called by muse, mutect2, varscan2
- ARMC9 | c.732C>G p.V244= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV63020928; called by muse, mutect2, varscan2
- ATP13A2 | c.1806G>C p.V602= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV58700571; called by muse, mutect2, varscan2
- ATP6AP2 | c.519G>A p.L173= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV101011553, COSV65797665; called by muse, mutect2, varscan2
- ATXN1 | c.2214C>G p.L738= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs377559897; called by muse, mutect2, varscan2
- AVIL | c.1542C>T p.L514= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV57681188, COSV57681859; called by muse, mutect2, varscan2
- B3GNT7 | c.195G>A p.P65= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs750337710, COSV55006465; called by muse, mutect2, varscan2
- B4GAT1 | c.426G>A p.L142= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100240071; called by muse, mutect2
- BCLAF1 | c.1776T>A p.I592= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV62142152; called by muse, mutect2, varscan2
- BICD2 | c.2319C>T p.D773= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs370848787; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA1I | c.66C>T p.T22= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV60808316; called by muse, mutect2, varscan2
- CCDC102B | c.1470G>A p.Q490= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV60134812, COSV60142402; called by muse, mutect2, varscan2
- CCDC38 | c.579G>C p.L193= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV100717932, COSV60183114; called by muse, mutect2, varscan2
- CDC42BPG | c.3861C>A p.L1287= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1356978557, COSV100711900; called by muse, mutect2, varscan2
- CHD4 | c.4464G>A p.L1488= (on ENST00000357008 / NM_001363606.2; = p.L1501= on NM_001273.5) | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100537997, COSV58901234; called by muse, mutect2, varscan2
- CHID1 | c.339G>A p.L113= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs558261531, COSV60259120; called by muse, mutect2, varscan2
- CLDN5 | c.132G>A p.Q44= (on ENST00000618236 / NM_001363066.2; = p.Q129= on NM_003277.4) | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- CNOT3 | c.1695G>A p.L565= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV55363282, COSV55366654; called by muse, mutect2, varscan2
- COA3 | c.57C>T p.F19= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs760925996, COSV55904786; called by muse, mutect2, varscan2
- COL1A2 | c.4008A>G p.P1336= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV51958072; called by muse, mutect2, varscan2
- CTC1 | c.63C>G p.V21= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV59853307; called by muse, mutect2, varscan2
- CUL1 | c.639G>C p.L213= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV57388689; called by muse, mutect2, varscan2
- CX3CR1 | c.1038G>A p.T346= | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as rs778240643, COSV64193915, COSV64194263; called by muse, mutect2, varscan2
- CYP4F12 | c.894C>T p.F298= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as COSV104410439, COSV61173187; called by muse, mutect2, varscan2
- DAGLA | c.2007G>T p.G669= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV57196085; called by muse, mutect2, varscan2
- DCTN3 | c.312G>A p.V104= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99426663; called by muse, mutect2, varscan2
- DCUN1D5 | c.423C>T p.I141= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV52784517; called by muse, mutect2, varscan2
- DDX60L | c.2817C>T p.L939= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1024425491, COSV99486709; called by muse, mutect2
- DIDO1 | c.6321C>T p.G2107= | Silent (SNP) | VAF 43/171 reads (25%) | catalogued as rs1381704627, COSV56622334; called by muse, mutect2, varscan2
- DOLK | c.474G>A p.S158= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs1427013359, COSV58280798; called by muse, mutect2, varscan2
- DPAGT1 | c.48C>T p.I16= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs1020413992, COSV62614402; called by muse, mutect2, varscan2
- DSC2 | c.321G>A p.K107= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV51864655, COSV99199563; called by muse, mutect2, varscan2
- DSP | c.5718C>T p.I1906= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV65792728; called by muse, mutect2, varscan2
- DSP | c.5940C>G p.L1980= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV101131176, COSV65792733; called by muse, varscan2
- DSP | c.6639C>T p.I2213= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV101131150, COSV65791675; called by muse, mutect2
- DSP | c.7131C>A p.I2377= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV101131151; called by muse, varscan2
- DSP | c.7215C>T p.L2405= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs191226040, COSV65792752; ClinVar: likely benign; called by muse, varscan2
- DSP | c.7656C>T p.L2552= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV65792766; called by muse, varscan2
- DSP | c.7731C>G p.V2577= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV65792771; called by muse, varscan2
- DUSP21 | c.93C>T p.L31= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs745699758, COSV59134165; called by muse, mutect2, varscan2
- DUXA | c.351C>T p.I117= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV73729688; called by muse, mutect2, varscan2
- E2F3 | c.132C>T p.F44= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs746277803, COSV60895863, COSV60897568, COSV60900585; called by muse, mutect2
- EFHC2 | c.1638C>T p.L546= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV59093317; called by muse, mutect2, varscan2
- EPHB2 | c.1920G>C p.L640= (on ENST00000400191 / NM_001309193.2; = p.L641= on NM_004442.7) | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV65862525; called by muse, mutect2, varscan2
- ERC2 | c.2193G>A p.E731= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV55622505; called by muse, mutect2, varscan2
- EXO1 | c.846C>T p.F282= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV62217560; called by muse, mutect2, varscan2
- F5 | c.5769C>T p.I1923= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV63123887; called by muse, mutect2, varscan2
- FANCI | c.660C>T p.L220= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV55522895, COSV55526978; called by muse, mutect2
- FARP1 | c.18G>A p.Q6= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV60337571; called by muse, mutect2, varscan2
- FCER2 | c.297G>A p.Q99= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV60916438; called by muse, mutect2, varscan2
- FCHO2 | c.1392G>A p.P464= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1316542038, COSV59272986; called by muse, mutect2, varscan2
- FLNB | c.6813C>T p.I2271= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs1298767359, COSV55879393; called by muse, mutect2, varscan2
- FLT4 | c.1725C>G p.L575= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV56108108; called by muse, mutect2, varscan2
- FNDC7 | c.1359C>T p.F453= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV54753660; called by muse, mutect2, varscan2
- FOXL2 | c.216G>A p.E72= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as CD025236, CD087432, COSV57726530; called by muse, mutect2, varscan2
- GABRA6 | c.1035C>G p.P345= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV50881321; called by muse, mutect2, varscan2
- GALK1 | c.564C>T p.F188= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV99848999; called by muse, mutect2
- GBE1 | c.93C>G p.L31= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV70099348; called by muse, mutect2, varscan2
- GNPAT | c.933G>A p.L311= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV64153456; called by muse, mutect2, varscan2
- GPR137 | c.111C>T p.L37= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV57402105; called by muse, mutect2, varscan2
- GPR6 | c.1088G>A p.*363= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV99253977; called by muse, mutect2, varscan2
- GREM2 | c.480G>A p.V160= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV58951054; called by muse, mutect2, varscan2
- GRHL1 | c.192C>G p.L64= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100257348; called by muse, mutect2
- GRID1 | c.888G>A p.R296= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs749819154, COSV60011987, COSV60057298; called by muse, mutect2, varscan2
- GRIN3A | c.2178C>G p.L726= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV62453044, COSV62453762; called by muse, mutect2, varscan2
- GUCA1A | c.498C>G p.L166= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV50004165; called by muse, mutect2, varscan2
- H2BC12 | c.69G>A p.Q23= | Silent (SNP) | VAF 19/164 reads (12%) | catalogued as rs1046403868, COSV63616809; called by muse, mutect2, varscan2
- H3-5 | c.183C>G p.L61= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV61187248; called by muse, mutect2, varscan2
- HEG1 | c.1048C>T p.L350= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV60762085; called by muse, mutect2, varscan2
- HPS6 | c.1911C>G p.L637= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV54625646; called by muse, mutect2, varscan2
- IFNW1 | c.19C>T p.L7= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV101207586; called by muse, mutect2
- KALRN | c.3822G>A p.E1274= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs147099139, COSV99561546; called by muse, mutect2
- KAT2B | c.1818C>T p.L606= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV55429375; called by muse, mutect2, varscan2
- KIDINS220 | c.1983C>T p.V661= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV56753428, COSV56760231; called by muse, mutect2, varscan2
- KIF13A | c.1125G>A p.E375= | Silent (SNP) | VAF 35/198 reads (18%) | catalogued as COSV52451224; called by muse, mutect2, varscan2
- KLHL42 | c.723C>G p.V241= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV101179843, COSV67145650, COSV67145884; called by muse, mutect2, varscan2
- LILRA2 | c.1197C>G p.L399= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs1034254196, COSV52189568, COSV52191611; called by muse, varscan2
- LLPH | c.378T>G p.G126= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV56981815; called by muse, mutect2, varscan2
- LRRC43 | c.324G>A p.L108= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV60289939; called by muse, mutect2, varscan2
- LRTOMT | c.312G>C p.L104= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV53825783; called by muse, mutect2, varscan2
- MAGI3 | c.1620G>A p.Q540= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV56835430; called by muse, mutect2, varscan2
- MAP3K1 | c.1915C>T p.L639= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV68123725; called by muse, mutect2, varscan2
- MAP3K19 | c.3237C>T p.L1079= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV59638897; called by muse, mutect2, varscan2
- MED16 | c.1936C>T p.L646= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs761913910, COSV54126382; called by muse, mutect2, varscan2
- MLKL | c.486G>A p.L162= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV58205131; called by muse, mutect2, varscan2
- MRGPRX1 | c.147C>A p.L49= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as COSV57105996, COSV57107296; called by muse, mutect2
- MRPL39 | c.756C>G p.V252= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs1447891622, COSV56260746; called by muse, mutect2, varscan2
- MSH4 | c.105C>G p.L35= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV54202867; called by muse, mutect2, varscan2
- MVP | c.2082G>C p.L694= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV62422038; called by muse, mutect2, varscan2
- MYH1 | c.1227C>T p.V409= | Silent (SNP) | VAF 35/242 reads (14%) | catalogued as rs556155732, COSV56847361; called by muse, mutect2, varscan2
- MYH11 | c.3420G>A p.Q1140= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs972414065, COSV55553235; called by muse, varscan2
- MYH6 | c.4842G>C p.L1614= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV62450400; called by muse, mutect2, varscan2
- MYH7 | c.4413G>A p.Q1471= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV62519235; called by muse, mutect2, varscan2
- MYO9B | c.1131G>A p.L377= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV68279142; called by muse, mutect2, varscan2
- NAP1L4 | c.879C>T p.F293= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV65881116; called by muse, mutect2, varscan2
- NCEH1 | c.84G>C p.P28= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV56434662; called by muse, mutect2, varscan2
- NCOA1 | c.2517G>A p.A839= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs757335592, COSV56044183; called by muse, mutect2, varscan2
- NEB | c.15132C>G p.V5044= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV51404527; called by muse, mutect2, varscan2
- NOL7 | c.546G>C p.L182= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV50581395; called by muse, mutect2
- NOS2 | c.432C>T p.I144= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs776919338, COSV58223783; called by muse, mutect2, varscan2
- NRG4 | c.54G>C p.L18= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV59638297; called by muse, mutect2, varscan2
- NUP188 | c.4821C>T p.F1607= | Silent (SNP) | VAF 61/281 reads (22%) | catalogued as rs755350781, COSV65330159; called by muse, mutect2, varscan2
- OR10X1 | c.762C>T p.F254= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as rs1428681863, COSV63767348; called by muse, mutect2
- OR1Q1 | c.321C>T p.F107= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as rs771925852, COSV52917895; called by muse, mutect2, varscan2
- OR51D1 | c.21G>A p.L7= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV62914181; called by muse, mutect2, varscan2
- OVOL2 | c.414C>G p.L138= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV53860230; called by mutect2, varscan2
- PALLD | c.2283C>G p.L761= (on ENST00000505667 / NM_001166108.2; = p.L744= on NM_016081.4) | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs753753166, COSV54980580; called by muse, mutect2, varscan2
- PANK1 | c.765G>A p.P255= (on ENST00000307534 / NM_148977.2; = p.P30= on NM_138316.4) | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs772935952, COSV56808139; called by muse, mutect2, varscan2
- PARP4 | c.2730G>A p.Q910= | Silent (SNP) | VAF 43/193 reads (22%) | catalogued as rs1310583884, COSV67961776; called by muse, mutect2, varscan2
- PARP8 | c.553C>T p.L185= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs764522092, COSV55860077; called by muse, mutect2, varscan2
- PAX5 | c.627G>C p.P209= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV63907396, COSV63907439; called by mutect2, varscan2
- PCDH10 | c.1101G>A p.V367= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV52093988; called by muse, mutect2, varscan2
- PDILT | c.189C>T p.L63= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs140659319; called by mutect2, varscan2
- PGLYRP1 | c.483G>A p.L161= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV50516828; called by muse, mutect2, varscan2
- PGM2L1 | c.762G>A p.S254= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1433185026, COSV53346885; called by muse, mutect2, varscan2
- PLPPR1 | c.330G>A p.L110= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV66453272; called by muse, mutect2, varscan2
- POLR2L | c.198G>A p.E66= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as rs1026278983, COSV58989935; called by muse, mutect2, varscan2
- PPFIBP2 | c.1830G>A p.K610= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV55077117; called by muse, mutect2, varscan2
- PRKCD | c.27C>T p.F9= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV57848607; called by muse, mutect2, varscan2
- PRR11 | c.810G>A p.L270= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs772261765, COSV51876590; called by muse, mutect2, varscan2
- PRR14 | c.1152C>G p.V384= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV54911775; called by muse, mutect2, varscan2
- PRRX2 | c.711C>G p.L237= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs768608876, COSV65242211; called by muse, mutect2, varscan2
- PRSS8 | c.963G>A p.L321= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs750432086, COSV99571040, COSV99571544; called by muse, varscan2
- PSMD6 | c.708C>G p.L236= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs749757883, COSV55759829; called by muse, mutect2, varscan2
- PTPRN | c.156C>T p.V52= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV55347929; called by muse, mutect2, varscan2
- PTPRZ1 | c.5349C>T p.I1783= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs923956277, COSV101100080, COSV66436559; called by muse, mutect2, varscan2
- RAB11FIP1 | c.579C>T p.I193= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV54760135; called by muse, mutect2, varscan2
- RAD54L2 | c.2760G>A p.L920= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV56578540; called by muse, mutect2, varscan2
- RALGPS1 | c.462C>T p.F154= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV52222091; called by muse, mutect2, varscan2
- RANGAP1 | c.1243C>T p.L415= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV62363461; called by muse, mutect2, varscan2
- RASGEF1C | c.903C>A p.I301= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV63180622; called by muse, mutect2, varscan2
- RBL1 | c.975C>T p.D325= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs764119167, COSV60329970; called by muse, mutect2, varscan2
- RBM12B | c.1620C>T p.F540= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs772666570, COSV67897964; called by muse, varscan2
- RBM43 | c.288T>C p.S96= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV58878747; called by muse, mutect2, varscan2
- REST | c.2223G>A p.Q741= | Silent (SNP) | VAF 64/275 reads (23%) | catalogued as COSV58360652; called by muse, mutect2, varscan2
- RSPH6A | c.1803C>T p.I601= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV55571763; called by muse, mutect2, varscan2
- RSRC2 | c.1304G>A p.*435= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV100063225, COSV59204343; called by muse, mutect2, varscan2
- SARDH | c.597C>G p.L199= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV53833322; called by muse, mutect2, varscan2
- SCN3A | c.4725G>A p.L1575= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV51809918; called by muse, mutect2, varscan2
- SDK1 | c.3105C>T p.L1035= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV67368896; called by muse, mutect2, varscan2
- SERINC3 | c.657C>T p.I219= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs200749563, COSV54856698; called by muse, mutect2, varscan2
- SESTD1 | c.1641T>C p.V547= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV58931288; called by muse, mutect2, varscan2
- SFI1 | c.756C>G p.L252= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV101191842; called by muse, mutect2
- SH3BGRL | c.54G>A p.K18= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV64620843; called by muse, mutect2, varscan2
- SH3GLB2 | c.270C>T p.N90= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs201505428, COSV65330899; called by muse, mutect2
- SLC34A2 | c.1482C>T p.F494= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs753853670, COSV65941491; called by muse, mutect2, varscan2
- SLC34A3 | c.774C>T p.I258= | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as rs1057283870, COSV63187058; called by muse, mutect2
- SLC6A18 | c.807C>T p.F269= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs137936927; called by muse, mutect2, varscan2
- SLC7A8 | c.1371G>A p.L457= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV57554052; called by muse, mutect2, varscan2
- SLC9A3 | c.1992C>T p.F664= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV53801193; called by muse, mutect2, varscan2
- SMG8 | c.2571G>A p.R857= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV56285228; called by muse, mutect2, varscan2
- SNRK | c.753G>A p.Q251= | Silent (SNP) | VAF 30/155 reads (19%) | catalogued as COSV56067992; called by muse, mutect2, varscan2
- SNX25 | c.222G>C p.L74= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV53014506; called by muse, mutect2, varscan2
- SP7 | c.987C>G p.L329= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV58190903; called by muse, mutect2
- ST6GAL1 | c.1095G>A p.T365= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs750161610, COSV51469679; called by muse, mutect2, varscan2
- STAT5A | c.1263G>A p.L421= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV61806727; called by muse, mutect2, varscan2
- STK31 | c.1581C>T p.F527= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV63456041; called by muse, mutect2, varscan2
- SWSAP1 | c.33C>G p.L11= (on ENST00000312423; = p.L32= on NM_175871.4) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV55800256; called by muse, mutect2, varscan2
- SYNE2 | c.16668C>T p.L5556= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV59939308, COSV59951021; called by muse, mutect2, varscan2
- TEX45 | c.456C>T p.F152= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1224973973, COSV64462995; called by muse, mutect2, varscan2
- TMCC1 | c.768C>T p.D256= | Silent (SNP) | VAF 46/266 reads (17%) | catalogued as rs759675425, COSV61440537; called by muse, mutect2, varscan2
- TMEM42 | c.228G>A p.V76= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs896147536, COSV56643860; called by muse, mutect2, varscan2
- TMPRSS11A | c.1140G>C p.L380= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV58358460; called by muse, mutect2, varscan2
- TNXB | c.4290G>A p.E1430= (on ENST00000647633; = p.E1183= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs757095620, COSV64478997; called by muse, mutect2, varscan2
- TOR1AIP2 | c.1266C>G p.L422= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs1224502527, COSV62626107; called by muse, mutect2, varscan2
- TPP1 | c.1290G>C p.L430= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV54990649; called by muse, mutect2
42 further variants in this file (0 protein-altering or splice-affecting, 25 silent, 17 other) are not listed here.
